Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5769, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5769-01A (Primary Tumor).

[page 1 of 2]
Summary tumor classification

pT3b, maximum tumor diameter 3.3 cm, Gleason 5+4=9, R1, pN0 (0/8).

Remark

In the previous punch biopsies the Gleason grading was 4+5=9. In the main preparation the undifferentiated were predominant, so the concluding classification is 5+4=9.

Additional immunohistochemical studies will follow to clarify the vascular status. The results will be presented in a follow-up report.

Microscopy

(Immunohistochemistry: CD31, D2-40).

In the additional immunohistochemical studies that have since been carried out in two representative tumor blocks, there is evidence of a tumor invasion of the lymph vessels. No evidence to suggest invasion of the blood vessels

The concluding tumor classification is thus as follows:

pT3b, maximum tumor diameter 3.3 cm, Gleason 5+4=9, L1, V0, R1, pN0 (0/8).

[page 2 of 2]
M930

Diagnosis

1. Predominantly undifferentiated, bilateral adenocarcinoma of the prostate extending across the organ (Gleason 5+4=9). Gleason 5 parts account for 60% of the tumor. Maximum tumor diameter 3.3 cm. Tumor infiltration of periprostatic fatty tissue in the right apical and left basolateral region (maximum invasion width 1.5 mm, maximum invasion depth 0.3 mm). Tumor involvement of the left seminal vesicle, extending focally to the blue-labeled preparation margin (contact line 1.6mm). Multifocal tumor involvement of perineural sheaths.

In addition, numerous foci of a prostatic intraepithelial neoplasia (high-grade PIN) and signs of myoglandular prostatic hyperplasia. Urothelium of prostatic urethra without dysplasia.

2. 6 tumor-free lymph nodes.

3. 2 tumor-free lymph nodes.

4. Tumor-free colon resection material.

Summary tumor classification

pT3b, maximum tumor diameter 3.3 cm, Gleason 5+4=9, R1, pN0 (0/8).

Remark

In the previous punch biopsies the Gleason grading was 4+5=9. In the main preparation the undifferentiated parts were predominant, so the concluding classification is 5+4=9.

Additional immunohistochemical studies will follow to clarify the vascular status. The results will be presented in a follow-up report.

Microscopy

(Immunohistochemistry: CD31, D2-40).

In the additional immunohistochemical studies that have since been carried out in two representative tumor blocks, there is evidence of a tumor invasion of the lymph vessels. No evidence to suggest invasion of the blood vessels

The concluding tumor classification is thus as follows:

pT3b, maximum tumor diameter 3.3 cm, Gleason 5+4=9, L1, V0, R1, pN0 (0/8).

Source: NCI Genomic Data Commons file edf87e9e-3aff-445d-99b4-a94cc9133590 (TCGA-CH-5769.7D49B105-6652-41B9-8E3A-E806A14DE604.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).